Somatic mutation profile of tumor specimen TCGA-19-5947-01A (aliquot TCGA-19-5947-01A-11D-1696-08) from TCGA case TCGA-19-5947, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 47.1 years (17,218 days).
Specimen TCGA-19-5947-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d367dca-c398-48f5-a0b5-2bd7cdee1497.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-5947-10A (Blood Derived Normal), aliquot TCGA-19-5947-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe362363-09b0-419f-847b-9d14f412e4d4

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Frame Shift Ins 4, Silent 4, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 31/125 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1057519942, COSV55881590; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DENND2A | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV52050138; called by muse, mutect2, varscan2
- IGDCC3 | c.2312A>T p.E771V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.16); catalogued as COSV60077245; called by muse, mutect2
- LMCD1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs199520704, COSV50087822; called by muse, mutect2, varscan2
- MAP3K20 | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV64377930; called by muse, mutect2, varscan2
- MSH4 | c.990G>A p.R330= | Splice Region (SNP) | VAF 30/135 reads (22%) | catalogued as COSV54200977; called by muse, mutect2, varscan2
- OTOGL | c.216G>T p.W72C (on ENST00000547103; = p.W63C on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV101509057; called by muse, mutect2
- POGLUT3 | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.107); catalogued as COSV60212321; called by muse, mutect2, varscan2
- RAG2 | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs149769148; called by muse, mutect2, varscan2
- RIMS1 | c.2165C>A p.P722H | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53450470; called by muse, mutect2, varscan2
- RPL5 | c.676T>C p.Y226H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1358595009, COSV59873340; called by muse, mutect2, varscan2
- SH3RF2 | c.1696G>A p.V566M | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs753470880, COSV63037716; called by muse, mutect2, varscan2
- SSTR2 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV59535745; called by muse, mutect2, varscan2
- TENT5C | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65616754; called by muse, mutect2, varscan2
- U2SURP | c.2810G>A p.R937H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.198); catalogued as rs1240444695, COSV67530553; called by muse, mutect2, varscan2
- ZNF135 | c.461C>T p.T154M (on ENST00000313434 / NM_001289401.2; = p.T166M on NM_003436.4) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as rs746765542, COSV57881402, COSV57884583; called by muse, mutect2, varscan2
- ZNF516 | c.2795C>T p.T932M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs370362208; called by muse, mutect2, varscan2
- AFF4 | c.2616dup p.S873Qfs*2 | Frame Shift Ins (INS) | VAF 21/100 reads (21%) | called by mutect2, pindel, varscan2
- DEPDC5 | c.3888_3889dup p.V1297Efs*27 (on ENST00000400246; = p.V1366Efs*21 on NM_014662.5) | Frame Shift Ins (INS) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- RBBP6 | c.3250dup p.I1084Nfs*11 | Frame Shift Ins (INS) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- RERE | c.1614dup p.Y539Ifs*3 | Frame Shift Ins (INS) | VAF 42/113 reads (37%) | called by mutect2, pindel, varscan2
- CXorf66 | c.957A>G p.A319= | Silent (SNP) | VAF 66/157 reads (42%) | catalogued as COSV65169120; called by muse, mutect2, varscan2
- ESAM | c.987T>G p.G329= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV54036050; called by muse, mutect2, varscan2
- PCDHA6 | c.1863G>A p.P621= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as rs782199993, COSV65343457; called by muse, mutect2, varscan2
- UBE2NL | c.93C>T p.N31= | Silent (SNP) | VAF 62/164 reads (38%) | catalogued as rs782717601; called by muse, mutect2, varscan2
- MIB1 | c.1829+6080G>A | Intron (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99838534, COSV99838964; called by muse, mutect2, varscan2
